Somatic mutation profile of tumor specimen TARGET-10-PATCDZ-09A (aliquot TARGET-10-PATCDZ-09A-01D) from TARGET case TARGET-10-PATCDZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.2 years (4,837 days).
Specimen TARGET-10-PATCDZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a5b5558-0310-4a1f-8e7c-c39f620d8196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCDZ-10A (Blood Derived Normal), aliquot TARGET-10-PATCDZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/908ab10e-fc14-47c9-85f6-536ef5d4570d

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 5, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1, 3'UTR 1, 3'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs998291881, COSV63662840; called by muse, mutect2, varscan2
- APBB3 | c.1358T>C p.L453P (on ENST00000357560 / NM_133173.2; = p.L460P on NM_006051.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.69); catalogued as COSV60365295; called by muse, mutect2, varscan2
- CACNA2D3 | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs764304504, COSV55531550, COSV99877758; called by muse, mutect2, varscan2
- CIAO3 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs149182704, COSV52401732; called by muse, mutect2, varscan2
- FANCD2 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.58); catalogued as COSV55036465; called by muse, mutect2, varscan2
- GRID2IP | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1392249890, COSV71849881; called by muse, mutect2, varscan2
- KLK9 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs942944016, COSV51591599; called by muse, mutect2, varscan2
- LRRN2 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1450950318, COSV65783577; called by muse, mutect2, varscan2
- NOTCH1 | c.4850_4851insGGG p.F1617delinsLG | In Frame Ins (INS) | VAF 6/25 reads (24%) | catalogued as COSV53033071, COSV53045239, COSV53052969, COSV53065728, COSV53095589; called by pindel, varscan2
- PHF6 | c.571G>T p.E191* (on ENST00000332070 / NM_032458.3; = p.E192* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 24/25 reads (96%) | catalogued as COSV59701471; called by muse, mutect2, varscan2
- RBBP4 | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV65132434; called by muse, mutect2, varscan2
- SAMD4A | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51879659; called by muse, mutect2, varscan2
- SEC16A | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs547371244, COSV51525906; called by muse, mutect2, varscan2
- SLC25A37 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51563758; called by muse, mutect2, varscan2
- SRGAP1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766337005, COSV61896823; called by muse, mutect2, varscan2
- TGFB2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65108757; called by muse, mutect2, varscan2
- ULK1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs758686407, COSV58856055; called by muse, mutect2, varscan2
- USP9X | c.4087-1G>T p.X1363_splice | Splice Site (SNP) | VAF 19/21 reads (90%) | catalogued as COSV61068407; called by muse, mutect2, varscan2
- ZFHX4 | c.9829C>A p.Q3277K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50692855; called by muse, mutect2, varscan2
- ZNF541 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV54544077; called by muse, mutect2, varscan2
- ACBD3 | c.758_761del p.Q253Lfs*57 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- MINDY3 | c.93A>G p.Q31= | Splice Region (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- NR3C1 | c.723_724insC p.N242Qfs*2 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel*, varscan2
- ZNF292 | c.1986_1987del p.D662Efs*4 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- AP3B2 | c.1404C>T p.V468= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs371731114, COSV55611917; called by muse, mutect2, varscan2
- DCLK1 | c.39C>T p.D13= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs756293091, COSV55189185; called by muse, mutect2, varscan2
- FRYL | c.1587A>T p.P529= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.352del p.*118= | Silent (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel*, varscan2
- PCDH9 | c.693G>A p.Q231= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV60540717; called by muse, mutect2, varscan2
- POLG | c.636G>A p.A212= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs1434195885, COSV99175005; called by muse, mutect2, varscan2
- RNF141 | c.438G>A p.V146= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs1173529127; called by muse, mutect2, varscan2
- THEG | c.138A>G p.E46= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- ATP2A2 | c.*3929A>G | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- ERBIN | c.818-165A>G | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- FANCD2P2 | n.864G>T | RNA (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- FBXL8 | chr16:67164276 G>C | 3'Flank (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- PHC1 | c.-57-9G>A | Intron (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- RASGRF1 | c.3542+14G>A | Intron (SNP) | VAF 24/72 reads (33%) | catalogued as rs761589956, COSV100293755; called by muse, mutect2, varscan2
- SRSF2 | c.*8-493A>G | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.34264+5561G>A | Intron (SNP) | VAF 29/119 reads (24%) | catalogued as rs780080272, COSV100626892; called by muse, mutect2, varscan2
